CCDI case PBCWSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/4d7bb2a8-b76d-47cc-b4f4-c106fea6953e

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1UIX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1UJK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1UJT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
